Somatic mutation profile of tumor specimen 0DD53I from CCDI case PBBLJE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 3.9 years (1,425 days).
Specimen 0DD53I: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1e3e35a6-8450-40a9-84ce-db03e54a3290.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DD53E (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f299e5c0-1c08-4a86-afa0-e35f1b771877

The open-access MAF lists 11 somatic variants for this specimen: 4 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 5, Missense Mutation 4, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDADC1 | c.1289T>C p.V430A | Missense Mutation (SNP) | VAF 22/749 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs1331987587; called by muse, mutect2
- TTC13 | c.2132C>T p.T711M | Missense Mutation (SNP) | VAF 264/618 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376123252; called by muse, varscan2
- COL4A4 | c.259C>T p.L87F | Missense Mutation (SNP) | VAF 42/472 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); called by muse, mutect2
- INPP5A | c.65T>G p.L22R | Missense Mutation (SNP) | VAF 20/165 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- C8B | c.1605G>A p.E535= | Silent (SNP) | VAF 56/470 reads (12%) | catalogued as rs777124688; called by muse, mutect2, varscan2
- COG7 | c.1710G>T p.A570= | Silent (SNP) | VAF 74/554 reads (13%) | called by muse, mutect2, varscan2
- LRATD1 | c.852C>G p.L284= | Silent (SNP) | VAF 312/5959 reads (5%) | catalogued as COSV54472845; called by muse, mutect2
- PTMA | c.321C>A p.T107= (on ENST00000341369 / NM_001099285.2; = p.T106= on NM_002823.5) | Silent (SNP) | VAF 46/297 reads (15%) | catalogued as COSV100398297; called by muse, mutect2, varscan2
- SLC39A12 | c.1371A>G p.G457= | Silent (SNP) | VAF 75/730 reads (10%) | called by muse, mutect2
- CFLAR | c.606+1015C>T | Intron (SNP) | VAF 25/614 reads (4%) | called by muse, mutect2
- NSFL1C | c.786-60T>A | Intron (SNP) | VAF 8/76 reads (11%) | called by muse, varscan2
